CCDI case PBCIHB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/4d4af558-0a7f-4f03-a29f-08f7dfb39d07

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 4.4 years (1,589 days).

Biospecimens (3 samples)
- Sample 0DSJY0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSJY9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSJYN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
